CCDI case PBBYHD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/acf2a613-ee57-4869-8afe-a528e40f02c7

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 8.1 years (2,947 days).

Biospecimens (3 samples)
- Sample 0DKPWC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKPWL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKPWY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
